Somatic mutation profile of tumor specimen 0DM8UF from CCDI case PBCAHA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Choroid plexus carcinoma; Tissue or organ of origin: Cerebrum; Age at diagnosis: 2.8 years (1,013 days).
Specimen 0DM8UF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52885192-fe82-4541-afa5-a43f3ba200c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM8U9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0873b3f4-ef4b-43a7-b3da-86728ef8dab9

The open-access MAF lists 21 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, 3'UTR 3, Intron 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAOA | c.860T>G p.L287R | Missense Mutation (SNP) | VAF 120/2588 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58643801; called by muse, mutect2
- PASD1 | c.2212G>T p.D738Y | Missense Mutation (SNP) | VAF 468/2203 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.125); catalogued as COSV100949569, COSV64855582; called by muse, mutect2, varscan2
- RPL10L | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 346/2061 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as rs1303053099, COSV100022706; called by muse, mutect2, varscan2
- UNC79 | c.1184G>A p.R395H (on ENST00000393151 / NM_001346218.2; = p.R218H on NM_020818.5) | Missense Mutation (SNP) | VAF 80/2103 reads (4%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.996); catalogued as rs145056871; called by muse, mutect2
- ABCB1 | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 299/1436 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CD300LF | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 398/958 reads (42%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- EGR3 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 278/1174 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.215); called by muse, mutect2
- PCDH12 | c.280C>G p.R94G | Missense Mutation (SNP) | VAF 36/1174 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PHF8 | c.2777A>C p.K926T (on ENST00000357988 / NM_001184896.1; = p.K890T on NM_015107.3) | Missense Mutation (SNP) | VAF 447/2330 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- TMEM150A | c.332A>C p.N111T (on ENST00000334462 / NM_001031738.3; = p.N58T on NM_153342.3) | Missense Mutation (SNP) | VAF 390/1976 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- USP49 | c.292T>C p.S98P | Missense Mutation (SNP) | VAF 68/708 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2
- DIDO1 | c.5769C>T p.F1923= | Silent (SNP) | VAF 251/1236 reads (20%) | catalogued as COSV56634840; called by muse, mutect2, varscan2
- EDA | c.184C>T p.L62= | Silent (SNP) | VAF 82/1793 reads (5%) | catalogued as COSV58878878; called by muse, mutect2
- SH3PXD2B | c.6G>A p.P2= | Silent (SNP) | VAF 254/313 reads (81%) | called by muse, mutect2, varscan2
- TONSL | c.735C>T p.C245= | Silent (SNP) | VAF 459/2102 reads (22%) | catalogued as rs767602201; called by muse, mutect2, varscan2
- ATP5IF1 | c.*16C>G | 3'UTR (SNP) | VAF 88/991 reads (9%) | called by muse, mutect2
- CAPS | chr19:5914119 T>A | 5'Flank (SNP) | VAF 30/1160 reads (3%) | called by muse, mutect2
- GUSB | c.*21G>A | 3'UTR (SNP) | VAF 352/771 reads (46%) | catalogued as rs754908402; called by muse, mutect2, varscan2
- SGPP1 | c.-8C>G | 5'UTR (SNP) | VAF 18/471 reads (4%) | called by muse, mutect2
- UBR5 | c.8102-52G>C | Intron (SNP) | VAF 70/450 reads (16%) | called by muse, mutect2, varscan2
- WIPI2 | c.*9T>A | 3'UTR (SNP) | VAF 38/1430 reads (3%) | called by muse, mutect2
